CCDI case PBBKFC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6f95afb0-8fa2-412b-b6cb-e7cf41c46faa

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.4 years (3,080 days).

Biospecimens (3 samples)
- Sample 0DAOS9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAOSA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAOSB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
